Somatic mutation profile of tumor specimen TCGA-HU-8249-01A (aliquot TCGA-HU-8249-01A-11D-2340-08) from TCGA case TCGA-HU-8249, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 76.7 years (28,012 days).
Specimen TCGA-HU-8249-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6d4c618-12d1-4590-af5c-7c4cf7a97602.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-8249-10A (Blood Derived Normal), aliquot TCGA-HU-8249-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/090e5d66-806d-43a2-ae97-cd8e0805ba3b

The open-access MAF lists 165 somatic variants for this specimen: 116 protein-altering or splice-affecting, 43 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 43, Nonsense Mutation 4, Intron 4, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, Splice Site 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs587782943, COSV57310950; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC6 | c.1072C>T p.L358F | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV52741040; called by muse, mutect2, varscan2
- AC097636.1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200518397; called by muse, mutect2, varscan2
- ACSBG2 | c.1823A>C p.Q608P | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV53124463; called by muse, mutect2, varscan2
- AKAP6 | c.3315T>A p.C1105* | Nonsense Mutation (SNP) | VAF 55/109 reads (50%) | catalogued as COSV55212791; called by muse, mutect2, varscan2
- ALG10B | c.714G>T p.L238F | Missense Mutation (SNP) | VAF 78/419 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV58143166; called by muse, mutect2, varscan2
- ANXA5 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56638841; called by muse, mutect2, varscan2
- APOA4 | c.1102C>T p.L368F | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs753408858, COSV63360405; called by muse, mutect2, varscan2
- AR | c.1642T>G p.L548V | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV65953920, COSV65956477; called by muse, mutect2, varscan2
- ARNT2 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs754379136, COSV57584939; called by muse, mutect2, varscan2
- ASPM | c.9029A>T p.K3010I | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.901); catalogued as COSV54129308; called by muse, mutect2, varscan2
- ATP10D | c.2926G>A p.V976M | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as COSV56707088, COSV99905069; called by muse, mutect2, varscan2
- BRINP3 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 70/334 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV66513604, COSV66513646; called by muse, mutect2, varscan2
- CACNA2D3 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 39/102 reads (38%) | catalogued as rs762052843, COSV55535998, COSV55580939; called by muse, mutect2, varscan2
- CDH18 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1253587457, COSV56908492; called by muse, mutect2, varscan2
- CEP126 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV54824866; called by muse, mutect2, varscan2
- CFHR5 | c.490A>G p.S164G | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs755352455, COSV56821578; called by muse, mutect2, varscan2
- CNGB3 | c.1436T>C p.V479A | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60689155; called by muse, mutect2, varscan2
- CNTNAP2 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV62176286; called by muse, mutect2, varscan2
- CNTNAP5 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV70484598; called by muse, mutect2, varscan2
- COL4A6 | c.3403G>T p.A1135S | Missense Mutation (SNP) | VAF 101/125 reads (81%) | SIFT tolerated (0.44); PolyPhen benign (0.145); catalogued as COSV57865633; called by muse, mutect2, varscan2
- CTTNBP2 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV50399425; called by muse, mutect2, varscan2
- DCLK1 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 109/335 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1310450357, COSV55179384; called by muse, mutect2, varscan2
- DENND1C | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs201113925; called by muse, varscan2
- DNAH8 | c.1406T>A p.I469N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV59443095; called by muse, mutect2, varscan2
- DNAJB1 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV54316901; called by muse, mutect2, varscan2
- DOCK6 | c.4225C>T p.R1409W | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.757); catalogued as rs779004684, COSV53914280; called by muse, mutect2, varscan2
- EPHA5 | c.1023T>A p.D341E | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV56643433; called by muse, mutect2, varscan2
- EYA2 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs780109158, COSV57942494; called by muse, mutect2, varscan2
- FAM110B | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 114/241 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs755553412, COSV64064194; called by muse, mutect2, varscan2
- FAM110C | c.301A>T p.I101F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV59655945; called by muse, mutect2, varscan2
- FASLG | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 83/156 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV60680101; called by muse, mutect2, varscan2
- FOSB | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as rs754837542, COSV62278611; called by muse, mutect2, varscan2
- FOXE1 | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64300388; called by muse, mutect2, varscan2
- FSIP2 | c.16961A>T p.N5654I | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV100556866; called by muse, mutect2, varscan2
- FSIP2 | c.20430G>T p.E6810D | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV100556870; called by muse, mutect2, varscan2
- GPR25 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.031); catalogued as COSV58498069; called by muse, mutect2, varscan2
- GRIK1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 112/148 reads (76%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.87); catalogued as rs975762689, COSV58717254; called by muse, mutect2, varscan2
- GRM2 | c.2228C>T p.T743M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403679566, COSV56584748; called by muse, mutect2, varscan2
- HDAC6 | c.2293C>A p.L765M | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.575); catalogued as COSV61928796; called by muse, mutect2, varscan2
- HSF2 | c.321T>G p.I107M | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63773859; called by muse, mutect2, varscan2
- IGHJ5 | c.18G>A p.W6* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as rs563513909; called by muse, mutect2, varscan2
- IGSF1 | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs763768928, COSV63837299; called by muse, mutect2, varscan2
- KCNA1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs746862982, COSV66836864; called by muse, mutect2, varscan2
- KDM6B | c.3787C>T p.R1263W | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54680631; called by muse, mutect2, varscan2
- KIAA1109 | c.13027A>G p.M4343V | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52671493; called by muse, mutect2, varscan2
- KIFC1 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 97/223 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV65728644, COSV65729169; called by muse, mutect2, varscan2
- KMO | c.671T>A p.I224N | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63806063; called by muse, mutect2, varscan2
- LAMA4 | c.3221G>A p.R1074H (on ENST00000230538 / NM_001105206.3; = p.R1067H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782099866, COSV57896212; called by muse, mutect2, varscan2
- LINGO2 | c.515C>A p.A172E | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58059525; called by muse, mutect2, varscan2
- LIPN | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs747108736, COSV68383880; called by muse, mutect2, varscan2
- LRTM1 | c.394A>G p.N132D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1379862105, COSV55536007; called by muse, mutect2, varscan2
- MAGOH | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV65161123, COSV65161228; called by muse, mutect2, varscan2
- MBD6 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs746095083, COSV100851865, COSV63074308; called by muse, mutect2, varscan2
- MED24 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100673038, COSV62418408; called by muse, mutect2, varscan2
- MUC17 | c.10403C>T p.T3468M | Missense Mutation (SNP) | VAF 134/603 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs763016905, COSV60280694; called by muse, mutect2, varscan2
- MUC5AC | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.1); catalogued as rs754238142, COSV62253881; called by muse, mutect2, varscan2
- MYO16 | c.4676C>T p.A1559V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV62749716; called by muse, mutect2, varscan2
- MYO9A | c.5020A>C p.K1674Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.216); catalogued as COSV61850502; called by muse, mutect2, varscan2
- MYRIP | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV56868239; called by muse, mutect2, varscan2
- NEK1 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV71455939; called by muse, mutect2, varscan2
- NUP188 | c.4076C>T p.T1359I | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV65361917; called by muse, mutect2, varscan2
- NXPH2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV55640382; called by muse, mutect2, varscan2
- OBSCN | c.15182G>A p.R5061H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs752585230, COSV52770925; called by muse, mutect2, varscan2
- OR13C4 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52926555; called by muse, mutect2, varscan2
- OR1L1 | c.778C>G p.P260A (on ENST00000373686; = p.P210A on NM_001005236.3) | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV58935544; called by muse, mutect2, varscan2
- OR5J2 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV56620474, COSV56621112; called by muse, mutect2, varscan2
- OR5M10 | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375060609, COSV73242269; called by muse, mutect2, varscan2
- PCDHA2 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 173/207 reads (84%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1300605850, COSV65366143; called by muse, mutect2, varscan2
- PIBF1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1297596367, COSV58322690; called by muse, mutect2
- PIGZ | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs202160888, COSV53013540; called by muse, mutect2, varscan2
- PKIA | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61914264; called by muse, mutect2, varscan2
- PPP3CA | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 161/414 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59922207; called by muse, mutect2, varscan2
- PTGDR | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV60093740, COSV60095311; called by muse, mutect2, varscan2
- RAB2B | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67235501; called by muse, mutect2, varscan2
- RAP2A | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55355002; called by muse, varscan2
- RBM33 | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1218284203, COSV56632030; called by muse, mutect2, varscan2
- RNF123 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV59686453, COSV59686922; called by muse, mutect2, varscan2
- RXFP3 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV57505431; called by muse, mutect2, varscan2
- RYR1 | c.9500G>A p.R3167Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV62096316; called by muse, mutect2, varscan2
- SEMA6B | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); catalogued as COSV56703585; called by muse, mutect2
- SENP7 | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs200753653; called by muse, mutect2, varscan2
- SIM1 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53491812; called by muse, mutect2, varscan2
- SLC35B2 | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 145/581 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV51489092; called by muse, mutect2, varscan2
- SLITRK2 | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59425120; called by muse, mutect2, varscan2
- SPRTN | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as rs775787648, COSV50478111; called by muse, mutect2, varscan2
- SSU72P8 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 67/255 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768877309; called by muse, mutect2, varscan2
- STT3B | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as COSV55502541; called by muse, mutect2, varscan2
- SYNDIG1L | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1320621720, COSV59047453; called by muse, mutect2, varscan2
- TANC2 | c.4759C>T p.R1587W | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1233680392, COSV67333923; called by muse, mutect2, varscan2
- TASOR | c.3527A>G p.H1176R (on ENST00000355628 / NM_001365636.2; = p.H800R on NM_015224.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62927702; called by muse, mutect2
- THBS2 | c.1241C>G p.T414S | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.047); catalogued as COSV64678000, COSV64678662, COSV64679862; called by muse, mutect2
- TLN1 | c.7556G>A p.R2519Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV59206690; called by muse, mutect2, varscan2
- TMEM200A | c.888T>G p.N296K | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51652563; called by muse, mutect2, varscan2
- TMPRSS7 | c.1463C>T p.S488F (on ENST00000452346; = p.S362F on NM_001042575.2) | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.087); catalogued as rs140725969, COSV69980562, COSV69982321; called by muse, mutect2, varscan2
- TNFSF10 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs764242132, COSV53843234; called by muse, mutect2, varscan2
- TTC37 | c.4599A>C p.K1533N | Missense Mutation (SNP) | VAF 47/56 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62454632; called by muse, mutect2, varscan2
- TTN | c.54707A>C p.K18236T (on ENST00000591111; = p.K10812T on NM_003319.4) | Missense Mutation (SNP) | VAF 20/30 reads (67%) | PolyPhen probably damaging (0.997); catalogued as COSV60034042; called by muse, mutect2, varscan2
- TTN | c.43902G>C p.K14634N (on ENST00000591111; = p.K7210N on NM_003319.4) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | PolyPhen probably damaging (0.997); catalogued as COSV60034081; called by muse, mutect2, varscan2
- UBA7 | c.2636G>T p.S879I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV60967548; called by muse, mutect2, varscan2
- USH2A | c.2588A>G p.K863R | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs753032286, COSV56364732; called by muse, mutect2, varscan2
- USP34 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1033413928, COSV68400973; called by muse, mutect2, varscan2
- ZBTB38 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs373571983; called by muse, mutect2, varscan2
- ZFHX3 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as rs142313117; called by muse, mutect2, varscan2
- ZNF100 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59747633, COSV59747949; called by muse, mutect2, varscan2
- ZNF462 | c.2121T>G p.I707M | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52934315, COSV52937334; called by muse, mutect2, varscan2
- ZNF648 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.427); catalogued as rs1390804798, COSV60570273; called by muse, mutect2, varscan2
- ZNF697 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as rs1479943429, COSV70284103; called by muse, mutect2, varscan2
- ATM | c.8431_8432del p.K2811Vfs*3 | Frame Shift Del (DEL) | VAF 50/84 reads (60%) | called by mutect2, pindel, varscan2
- CDH10 | c.1571_1572insG p.F524Lfs*17 | Frame Shift Ins (INS) | VAF 48/147 reads (33%) | called by mutect2, pindel, varscan2
- CTR9 | c.847_849+22del p.X283_splice | Splice Site (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- CUL9 | c.6005_6007del p.V2002del | In Frame Del (DEL) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- ENKUR | c.311A>T p.N104I | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ITPR2 | c.6829_6830dup p.M2277Ifs*19 | Frame Shift Ins (INS) | VAF 79/137 reads (58%) | called by mutect2, pindel, varscan2
- TRAV26-1 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF227 | c.2147del p.H716Lfs*104 | Frame Shift Del (DEL) | VAF 46/150 reads (31%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.3180G>A p.T1060= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs201516498; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- AGBL2 | c.1299C>T p.T433= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs759625602, COSV54090498; called by muse, mutect2, varscan2
- ARHGEF12 | c.921A>T p.A307= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV63104426; called by muse, mutect2, varscan2
- ASXL1 | c.4242C>T p.P1414= | Silent (SNP) | VAF 51/257 reads (20%) | catalogued as COSV60107509; called by muse, mutect2, varscan2
- C6 | c.2517C>T p.D839= | Silent (SNP) | VAF 63/172 reads (37%) | catalogued as rs567176554, COSV54707923; called by muse, mutect2, varscan2
- CDHR2 | c.1131C>T p.D377= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs551349879, COSV56142114; called by muse, mutect2
- CEACAM5 | c.1827G>A p.A609= | Silent (SNP) | VAF 94/214 reads (44%) | catalogued as rs782555811, COSV55752088; called by muse, mutect2, varscan2
- CIR1 | c.492G>A p.S164= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs763864312, COSV59595974; called by muse, mutect2, varscan2
- CPM | c.276G>A p.L92= | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as COSV58033071; called by muse, mutect2, varscan2
- CYTIP | c.930C>T p.S310= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as rs1472328125, COSV51633576, COSV51633945; called by muse, mutect2, varscan2
- DPY19L2 | c.816G>C p.L272= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV60543157; called by muse, mutect2, varscan2
- FAM98A | c.318G>A p.K106= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV53210114; called by muse, mutect2, varscan2
- FAT2 | c.4083G>A p.T1361= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as rs1326724360, COSV55819089; called by muse, mutect2, varscan2
- GPM6A | c.255C>A p.I85= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV54541215; called by muse, mutect2, varscan2
- HTR1B | c.321C>T p.T107= | Silent (SNP) | VAF 69/176 reads (39%) | catalogued as COSV64051431; called by muse, mutect2, varscan2
- KDM5C | c.1203C>T p.A401= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as rs782716338, COSV64764700; ClinVar: benign; called by muse, mutect2, varscan2
- LBX1 | c.162C>T p.C54= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV64621563; called by muse, mutect2, varscan2
- LDHA | c.918G>T p.V306= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV57039996; called by muse, mutect2, varscan2
- MIER2 | c.180C>T p.C60= | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as rs957451956, COSV53395563; called by muse, mutect2, varscan2
- NCAM1 | c.1545C>T p.I515= (on ENST00000316851 / NM_181351.5; = p.I505= on NM_000615.7) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs782763937, COSV57515939; called by muse, mutect2, varscan2
- NLRC5 | c.1671C>G p.L557= | Silent (SNP) | VAF 76/195 reads (39%) | catalogued as COSV52654571; called by muse, mutect2, varscan2
- NOVA1 | c.1500T>C p.A500= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs1030705607, COSV57476274; called by muse, mutect2, varscan2
- OMD | c.54A>G p.V18= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV65020166; called by muse, mutect2, varscan2
- OR2L3 | c.888G>T p.V296= | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as COSV63455117; called by muse, mutect2, varscan2
- PALB2 | c.609A>G p.K203= | Silent (SNP) | VAF 45/174 reads (26%) | catalogued as COSV55164935; called by muse, mutect2, varscan2
- PAX3 | c.564C>T p.I188= | Silent (SNP) | VAF 37/168 reads (22%) | catalogued as COSV51338856; called by muse, mutect2, varscan2
- PCDHA10 | c.48G>A p.S16= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as rs1031755500; called by muse, mutect2
- PLA2G6 | c.1725G>A p.T575= | Silent (SNP) | VAF 76/144 reads (53%) | catalogued as rs200599704; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PPP1R1C | c.36C>T p.A12= | Silent (SNP) | VAF 25/146 reads (17%) | catalogued as rs758312542, COSV54715615; called by muse, mutect2, varscan2
- PPP1R3A | c.1716C>A p.I572= | Silent (SNP) | VAF 55/120 reads (46%) | catalogued as COSV52881742; called by muse, mutect2, varscan2
- PRPF6 | c.894C>G p.L298= | Silent (SNP) | VAF 42/266 reads (16%) | catalogued as COSV53870155, COSV53877547; called by muse, mutect2, varscan2
- PTCHD1 | c.1515T>A p.V505= | Silent (SNP) | VAF 89/107 reads (83%) | catalogued as COSV65059990; called by muse, mutect2, varscan2
- PTPN23 | c.1938C>T p.D646= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV55544410; called by muse, mutect2, varscan2
- RAD23A | c.312G>A p.P104= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs369559169; called by muse, mutect2, varscan2
- RNF126 | c.666C>T p.H222= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs370629184; called by muse, mutect2, varscan2
- ROBO2 | c.930C>G p.V310= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV59909802; called by muse, mutect2, varscan2
- RYR3 | c.6453G>A p.A2151= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs770216543, COSV101211891, COSV66787409; called by muse, mutect2, varscan2
- SMC2 | c.1194T>C p.L398= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs184176278; called by muse, mutect2, varscan2
- SMOC1 | c.861C>T p.Y287= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs761319347, COSV62759794; called by muse, mutect2
- SPTAN1 | c.3030C>T p.N1010= | Silent (SNP) | VAF 106/258 reads (41%) | catalogued as rs202129574, COSV63986928; ClinVar: likely benign; called by muse, mutect2, varscan2
- TDRD6 | c.873G>A p.T291= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as rs1397670394, COSV100288142, COSV60175436; called by muse, mutect2, varscan2
- TNXB | c.10401C>T p.T3467= (on ENST00000647633; = p.T3220= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as rs1180245199, COSV64478417; called by muse, mutect2, varscan2
- TPO | c.1464C>T p.A488= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as rs202005839, COSV61096934; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1333G>A | Intron (SNP) | VAF 36/145 reads (25%) | catalogued as COSV63751708; called by muse, mutect2, varscan2
- ATG4D | c.1122+17G>A | Intron (SNP) | VAF 29/129 reads (22%) | catalogued as COSV100470507; called by muse, mutect2, varscan2
- KCNIP4 | c.62-421154T>C | Intron (SNP) | VAF 11/78 reads (14%) | catalogued as COSV66171795; called by muse, mutect2, varscan2
- OR6T1 | c.*2C>G | 3'UTR (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100190235, COSV58310375; called by muse, mutect2, varscan2
- TTC8 | c.115-5738G>T | Intron (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100581734; called by muse, mutect2, varscan2
- VPS11 | c.-285A>G | 5'UTR (SNP) | VAF 7/38 reads (18%) | catalogued as COSV56184949; called by muse, mutect2, varscan2
